Somatic mutation profile of tumor specimen TCGA-SR-A6MR-01A (aliquot TCGA-SR-A6MR-01A-11D-A35I-08) from TCGA case TCGA-SR-A6MR, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Extra-adrenal paraganglioma, malignant; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 41.0 years (14,991 days).
Specimen TCGA-SR-A6MR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 308e6720-3c0a-4d87-bcf0-a4c6dd01d1a8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-SR-A6MR-10A (Blood Derived Normal), aliquot TCGA-SR-A6MR-10A-01D-A35G-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2cb7da6d-7d47-4a66-a8b1-b2ae5d0e7354

The open-access MAF lists 9 somatic variants for this specimen: 9 protein-altering or splice-affecting.
By variant classification: Missense Mutation 8, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SPG11 | c.23C>G p.A8G | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs200939573, COSV55997076; called by muse, mutect2
- ST6GAL1 | c.1162G>T p.E388* | Nonsense Mutation (SNP) | VAF 7/55 reads (13%) | catalogued as COSV51467110, COSV51473610, COSV99398101; called by muse, mutect2, varscan2
- TTN | c.17768G>T p.R5923L (on ENST00000591111; = p.R4996L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/95 reads (31%) | PolyPhen benign (0.203); catalogued as rs761993856, CM1510359, COSV60054985; called by muse, mutect2, varscan2
- DMWD | c.735C>G p.H245Q | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT tolerated (0.5); PolyPhen benign (0.226); called by muse, mutect2, varscan2
- GPS1 | c.58G>A p.D20N | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.415); called by muse, mutect2, varscan2
- H2AX | c.161C>T p.A54V | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.755); called by muse, mutect2, varscan2
- POLR3A | c.1798A>G p.I600V | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT tolerated (0.79); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- RPL27A | c.75C>A p.H25Q | Missense Mutation (SNP) | VAF 17/120 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- SLIT1 | c.2821C>G p.H941D | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT tolerated (0.59); PolyPhen benign (0.061); called by muse, mutect2
